Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A3BT, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A3BT-01A (Primary Tumor).

[page 1 of 2]
		lw 10/15/11

FINAL DIAGNOSIS -----

1. RIGHT INFERIOR PARATHYROID (BIOPSY): CELLULAR PARATHYROID TISSUE (9.0 MG).

2. THYROID (TOTAL THYROIDECTOMY):

SPECIMEN TYPE: Total thyroidectomy

TUMOR SITE: Isthmus

HISTOLOGIC TYPE: Papillary carcinoma, tall cell variant

TUMOR SIZE: Greatest dimension: 2.5 cm

LOCAL EXTENSION:

Tumor extends into thyroid capsule but does not show extrathyroidal extension

FOCALITY: Unifocal

LYMPH NODES:

Metastatic carcinoma in 2 of 7 lymph nodes

EXTENT OF INVASION

PRIMARY TUMOR:

pT2: Tumor > 2cm but < 4cm, limited to thyroid

REGIONAL LYMPH NODES:

pN1b: Metastasis to cervical or mediastinal nodes (2/7)

DISTANT METASTASIS:

pMX: Cannot be assessed

MARGINS:

Margins are uninvolved (tumor abuts inked margin at multiple locations but does not extend to it)

VENOUS/LYMPHATIC INVASION:

Not definitively identified

ADDITIONAL PATHOLOGIC FINDINGS:

Five separate papillary microcarcinomas are identified, two in the right lobe (1.5 and 0.25 mm) and three in the left lobe (1.2, 0.9, and 0.6 mm).

NOTE: This case was shown at the

ICD O-3
carcinoma, papillary, tall cell variant
8344/3
Site: thyroid, NOS
C73.9
lw 10/15/11

[page 2 of 2]
3. LEFT NECK LEVEL III AND IV LYMPH NODES (MODIFIED LEFT NECK DISSECTION): METASTATIC PAPILLARY THYROID CARCINOMA INVOLVING TWO
(2) OF SEVEN (7) LYMPH NODES.

Source: NCI Genomic Data Commons file 11f93215-95bc-4e50-aa2a-b55b778ed84b (TCGA-ET-A3BT.66200460-5621-4F64-A7D2-ECDF3793D63C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).